CCDI case PBBZLU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/5c81cab3-0085-46d3-a22b-126fbe3aa2f3

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, small cell, nonkeratinizing: ICD-O-3 morphology code: 8073/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 14.0 years (5,130 days).

Biospecimens (3 samples)
- Sample 0DLJWI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLJWR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLJX5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
